Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABF0, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABF0-TTP1-A (Primary Tumor).

[page 1 of 18]
Surgical Pathology Final Report
Temporary Copy

Exceptional Responder # 9671

Case: [REDACTED]
Collected: [REDACTED] -7
Ordered by: [REDACTED]

P
P
H
Lo

Specimen Source

- A Breast, RIGHT, 2 O'CLOCK
- B Breast, LEFT LOWER OUTER
- C Breast, LEFT UPPER OUTER
- D Breast, LEFT AXILLARY NODE

Clinical Information

- A) Part A is from 2 o'clock, small solid nodule, fibroadenoma versus malignancy.
- B) Left lower outer, invasive malignant mass.
- C) Left upper outer, invasive malignant mass.
- D) Left axillary node, looks involved with metastasis.

The specimen was placed in formalin at [REDACTED] The specimen will meet formalin fixation guidelines.

Gross Description

Part A. Submitted in a container of formalin labelled [REDACTED] #1, right 2 o'clock" are four tan needle core biopsies ranging in size from 1.1 to 0.7 cm in length. They are submitted entirely in A1.

Gross Summary:

Specimen Type: needle biopsies

Laterality: right

Tumor Site: 2 o'clock

Time in Formalin Between 6 and 48 Hours (Yes/No): yes

Part B. Submitted in a container of formalin labelled [REDACTED] #2, left lower outer" are four tan needle core biopsies ranging in size from 1.5 to 1 cm in length. They are submitted entirely in B1.

Gross Summary:

Specimen Type: needle biopsies

Laterality: left

Tumor Site: lower outer

Time in Formalin Between 6 and 48 Hours (Yes/No): yes

Part C. Submitted in a container of formalin labelled [REDACTED] #3, upper outer" are four tan needle core biopsies ranging in size from 2.7 to 1.7 cm in length. They are submitted entirely in C1.

Gross Summary:

Specimen Type: needle biopsies

Laterality: left

[page 2 of 18]
Surgical Pathology Final Report

Temporary Copy

Case: [REDACTED]
Collected: [REDACTED] -7
Ordered by: [REDACTED]

Exceptional Responder # 9671

P: [REDACTED]
Pa: [REDACTED]
ID: [REDACTED]
Lo: [REDACTED]

Tumor Site: upper outer

Time in Formalin Between 6 and 48 Hours (Yes/No): yes

Part D. Submitted in a container of formalin labelled [REDACTED] "left axillary lymph node" are four tan needle core biopsies ranging in size from 2 to 1.4 cm in length. They are submitted entirely in D1.

Microscopic Description

Microscopic examination was performed.

Pathologist Comment

Tumor is present in one of four needle biopsies in specimen A (right side), nearly identical to those on the left side. The other three biopsies are totally dissimilar, and show fibroadenoma. Clinical correlation required to confirm that all biopsies in specimen A are from the right side.

Diagnosis

A. Breast, right 2 o'clock, needle biopsies

- fibroadenoma (three fragments)
- invasive duct carcinoma (one fragment), see comment.

Diagnostic Summary:

Histologic Type: invasive duct carcinoma

Histologic Grade (modified SBR): grade 3

Tubule formation score: 3

Nuclear pleomorphism score: 3

Mitotic count score: 3

Total score: 9/9

Type of in situ component: not identified

Vascular/lymphatic involvement: identified

Calcifications: not identified

Prognostic markers: pending

/

B. Breast, left lower outer, needle biopsies

- invasive duct carcinoma.

Diagnostic Summary:

Histologic Type: invasive duct carcinoma

Histologic Grade (modified SBR): grade 3

Tubule formation score: 3

Nuclear pleomorphism score: 3

[page 3 of 18]
Surgical Pathology Final Report

Exceptional Responder # 9671

Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

-7

Mitotic count score: 3

Total score: 9/9

Type of in situ component: not identified

Vascular/lymphatic involvement: identified

Calcifications: not identified

Prognostic markers: pending

/

C. Breast, left upper outer, needle biopsies

- invasive duct carcinoma.

Diagnostic Summary:

Histologic Type: invasive duct carcinoma

Histologic Grade (modified SBR): grade 3

Tubule formation score: 3

Nuclear pleomorphism score: 3

Mitotic count score: 3

Total score: 9/9

Type of in situ component: not identified

Vascular/lymphatic involvement: identified

Calcifications: not identified

Prognostic markers: pending

/

D. Breast, left axillary node, biopsy

- invasive duct carcinoma

- tumor appears to involve a nearly obliterated lymph node

[page 4 of 18]
Surgical Pathology Addendum Report

Exceptional Responder # 9671

Temporary Copy

Case: [REDACTED]
Collected: [REDACTED] -7
Ordered by: [REDACTED]

P: [REDACTED]
Pa [REDACTED]
ID [REDACTED]
Lo [REDACTED]

Discussion

This breast cancer prognostic panel was performed at [REDACTED]
[REDACTED] using assisted quantitative image analysis by ChromaVision.

Diagnosis

IMAGE ANALYSIS:

BLOCK B1

ESTROGEN RECEPTOR	0%
Prognostic Category	Unfavorable
PROGESTERONE RECEPTOR	0%
Prognostic Category	Unfavorable
Her-2/Neu	4.4
Prognostic Category	Overexpression
Ki-67	34%
Prognostic Category	Unfavorable

IMAGE ANALYSIS:

BLOCK C1

ESTROGEN RECEPTOR	0%
Prognostic Category	Unfavorable
PROGESTERONE RECEPTOR	0%
Prognostic Category	Unfavorable
Her-2/Neu	3.9
Prognostic Category	Overexpression
Ki-67	33%
Prognostic Category	Unfavorable

Interpretive Guide:

Immunocytochemical receptor studies are reported as a percent of tumor nuclei that express immunoreactivity. For breast cancer, estrogen receptor and progesterone receptor positivity of 5% or greater is considered a favorable prognostic indicator. A Her-2/Neu of 2 or greater is unfavorable. For the cell proliferation marker Ki-67, greater than 20% positivity is unfavorable.

[REDACTED]

[page 5 of 18]
Surgical Pathology Addendum Report

Temporary Copy

Page 2 of 2

Exceptional Responder # 9671

Case: [REDACTED]

Patient: [REDACTED]

Collected: [REDACTED] -7

ID: [REDACTED]

Ordered by: [REDACTED]

Location: [REDACTED]

(Electronically signed by)
[REDACTED]

Addendum Comment

IMMUNOHISTOCHEMISTRY

The performance characteristics of all immunohistochemical stains cited in this report were determined by the Diagnostic Immunohistochemistry Laboratory of [REDACTED] compliance with CLIA'88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA.

This testing was developed by the Diagnostic Immunohistochemistry Laboratory of [REDACTED]. It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

BREAST CANCER PROGNOSTIC PANEL WITH ACIS

METHODOLOGY: This prognostic panel was performed on formalin-fixed paraffin-embedded tissue sections, unless otherwise noted. Antibody types employed were: ER (Clone SP1), PgR (Clone 122), Ki-67 (Clone 30-9), and Her-2/neu (Clone 4B5). Detection of these antibodies was accomplished using the Ventana Biotin/Streptavidin-HRP 1-VIEW DAB Visualization System.

[page 6 of 18]
(Baseline)

+0

Results

(Accession) (Order)

CT CHEST ABDOMEN PELVIS W CONT

Status: Final result

+1

Results

Patient Information

Patient Name

Sex
Female

DOB

Study Result

Final

+0

INTERPRETATION

Exam: CT Chest, Abd, Pelvis, w/contrast~~Date/Time of Exam: ~~~~History: Breast ca 174.9.~~Technique: CT of the chest, abdomen, and pelvis was performed following the administration of intravenous contrast: 75 mL Optiray-240 and oral contrast.~~Findings: No old study is available for comparison. 3 mm subpleural nodule right lower lobe image 31. Few other tiny scattered nodules measuring 2 to 3 mm are present (example: lingula image 30, image 34). Small left pleural effusion. Left pleural thickening associated with this effusion. Left paracardiac soft tissue nodule measuring 8 mm on image 48. Small sliding hiatal hernia. No internal mammary lymphadenopathy. Bulky left axillary lymphadenopathy is present with centrally necrotic nodes measuring up to 2 cm short axis. There are multiple left breast masses present measuring up to approximately 4.5 cm. There is left breast skin thickening as well. Right breast mass is present on image 30 measuring 5 cm in greatest dimension. No evidence of right axillary lymphadenopathy, hilar or mediastinal lymphadenopathy.~~There are multifocal hepatic masses suspicious for metastatic disease measuring up to 4 cm. The gallbladder is unremarkable. The spleen, pancreas, gallbladder and adrenal glands are within normal limits. No significant renal pathology. Small amount of free pelvic fluid noted along the left lateral aspect of the rectum. Patient is status post hysterectomy.

No adnexal or urinary bladder pathology evident. Degenerative change is noted in the spine. There are subtle areas of sclerosis scattered around the skeleton, indeterminate for metastatic disease (left iliac crest image 90, right iliac bone image 105) as well as areas of subtle inhomogeneity of density in vertebral bodies.~~Impression: Small left pleural effusion with pleural thickening. Multiple left breast masses with skin thickening and left axillary lymphadenopathy which is partially necrotic and suspicious for metastatic disease. Right breast mass, nonspecific; mammograph, ultrasound and physical exam may be helpful in further assessment. Hepatic lesions suspicious for metastatic disease. Small amount of free pelvic fluid. No definite skeletal metastasis with minor findings as above.~~

Dictated By:

Exceptional Responder #9671

+0

Click here to view result

CT

Result History

Radiology Order Result History

Imaging

Imaging Questions and Documentation

Allergies as of

-3

Not on File

Future Appt

Future Appt

[page 7 of 18]
Exceptional Responder # 9671

IMAGING SERVICES

(Baseline) +0 PET	Exam Date/Time:	Phone #:	MRN:
	Sex:	Account #:	
	Female	Accession #:	Performing Department:
Pl. Class:	Ordering Provider:	Authorizing Provider:	

Result Narrative

Radionuclide PET Metabolic Tumor Imaging with CT Attenuation Correction and Anatomic Localization from Skull Base to Mid Thigh:--Radiopharmaceutical: F-18-Fluorodeoxyglucose Dose: 10.8 mCi--Reason for Consultation: Bilateral breast carcinoma with positive left axillary lymph node for initial staging evaluation--FDG (F-18-Fluorodeoxyglucose) PET imaging was performed at approximately one hour following intravenous infusion of the radiopharmaceutical agent using a dedicated PET / CT full ring detector with CT derived attenuation correction of PET data and anatomic localization. Imaging was performed from the skull base to mid thigh levels with subsequent reconstruction of full trunk, orthogonal view slices in transverse, sagittal, and coronal projections. Today's PET imaging examination is the first of a series and is performed concurrently with diagnostic CT examinations of the chest, abdomen and pelvis which will be subsequently correlated. Today's examination is interpreted in light of Breast biopsy results of reflecting invasive ductal carcinoma in a right 2:00 breast lesion as well as left lower outer and upper outer quadrant sites with a positive left axillary lymph node nearly completely replaced/obliterated.--Today's PET imaging examination demonstrates intense increase of metabolic activity in the known left upper and lower outer quadrant masses. A likely medial intramammary lymph node and two lateral intramammary lymph nodes demonstrate marked increase of metabolic activity as well as two distinctly separate enlarged left axillary lymph nodes. The maximal SUV value in these sites is 6.5 units.--The liver demonstrates focal masses of increased metabolic activity in the medial segment of the left lobe and posterior segment of the right upper lobe.--No focally increased metabolic activity is observed in the right breast at the 2:00 position or elsewhere.--Focally increased osseous turnover is present in the right femoral neck and appears to be located within the medullary cavity and associated with sclerotic changes on the CT portion of the examination. No other osseous abnormalities are identified.--Impression:--1. Multicentric left breast carcinoma with intramammary lymph node involvement

[page 8 of 18]
as well as enlarged left axillary lymph node involvement.~2. No evidence for focally increased metabolic activity in the right breast.~3. Liver metastases involving each lobe as above.~4. Findings in the left femoral neck of concern for a single osseous metastasis. Further evaluation of a medullary infiltrative process by MRI may be helpful in confirming or excluding early osseous metastasis at this time if considered clinically indicated.~

[REDACTED]

+0 The diagnostic CT examinations of the chest, abdomen and pelvis performed [REDACTED] were interpreted with [REDACTED] to demonstrate multiple left breast masses, left axillary lymphadenopathy, the right breast mass and hepatic lesions suspicious for metastasis. These findings are consistent with previously reported PET imaging examination findings of multicentric left breast disease with intramammary and left axillary lymph node involvement, liver metastases and a right femoral neck lesion consistent with metastasis.~Please note the right femoral neck lesion was misidentified as a left-sided lesion on the initial reported impression that was correctly located within the body of the examination.~

[REDACTED]

[REDACTED]

Exceptional Responder # 9671.

[REDACTED]

[REDACTED]

[REDACTED]

[page 9 of 18]
Exceptional Responder # 9671

IMAGING SERVICES

[Redacted] (Best response) PET	Exam Date/Time:	Phone #:	MRN:
	+161	[Redacted]	[Redacted]
	Sex:	Account #:	
	Female		
Ref. Class:	Accession #:	Performing Department:	
[Redacted]	[Redacted]	[Redacted]	

Result Narrative

Radiopharmaceutical: PET Metabolic Tumor Imaging, Restaging of Breast Carcinoma:

Radiopharmaceutical: F-18-Fluorodeoxyglucose Dose: 13 mCi

Reason for Consultation: Metastatic bilateral infiltrating ductal carcinoma.
Status post chemotherapy.
Reevaluation for disease extent.

After the intravenous administration of F-18-Fluorodeoxyglucose (FDG), a series of overlapping emission and transmission PET images were obtained on a dedicated full ring detector PET scanner. The area imaged spanned the region from the lower cerebrum through the upper thighs. Attenuation corrected planar 3-D images and volumetric tomographic images in the coronal, transaxial, and parasagittal projections were reviewed. A nondiagnostic, noncontrast, low resolution CT scan was performed in conjunction with this examination for the purposes of attenuation correction and anatomic localization. Today's study is compared with the previous examination dated [Redacted] +0

Evaluation of the imaged head and neck region demonstrates physiologic tracer distribution. Evaluation of the thorax demonstrates physiologic metabolic activity throughout both lung field regions as well as the mediastinum. The liver and spleen appear unremarkable. Metabolic activity also appears unremarkable throughout the abdomen and pelvis. Evaluation of the remainder of the imaged soft tissues of the body demonstrates a mild to at most mild to moderate irregular increase in metabolic activity throughout the anterior portions of both breasts. No absolute focal increase in metabolic activity is noted in either breast. Metabolic activity is unremarkable throughout the imaged bony skeleton.

Impression: +0
The previous examination [Redacted] demonstrated multiple metastatic lesions including in the left axilla, multiple areas in the left breast, and right femoral neck. These have all resolved metabolically. There is no obvious evidence for metabolically active metastatic disease on today's study.

[page 10 of 18]
Dictated By: [REDACTED]

Electronically Signed By: [REDACTED]

Date Signed: [REDACTED] +161
[REDACTED]

[REDACTED]

Exceptional Responder # 9671
[REDACTED]
[REDACTED]

[REDACTED]

[page 11 of 18]
Exceptional Responder # 9671

IMAGING SERVICES

(Latest Scan)

Exam Date/Time:	+4097	Phone #:	MRN:
Legal Sex:	Female	Account #:	
Accession #:		Performing Department:	
Pt. Class:	Outpatient		

Final - PET TUMOR IMG W CT SKL BSE MID THG

Reason for Exam: metastatic breast cancer, weight loss.

Diagnosis: BRCA2 gene mutation positive in female [Z15.01, Z15.02, Z15.09 (ICD-10-CM)]
Cancer, metastatic to liver [C78.7 (ICD-10-CM)]
Breast tenderness [N64.4 (ICD-10-CM)]
Weight loss [R63.4 (ICD-10-CM)]
Malignant neoplasm of female breast, unspecified estrogen receptor status, unspecified laterality, unspecified site of breast [C50.919 (ICD-10-CM)]

INTERPRETATION

Radionuclide PET Metabolic Tumor Imaging with CT Attenuation
Correction and Anatomic Localization from Skull Base to Mid Thigh:

Radiopharmaceutical: F-18-Fluorodeoxyglucose Dose: 13.4 mCi right arm IV

Time of Injection:

BMI: Not available/56.7 kg

Clinical Indication: Subsequent treatment strategy to evaluate metastatic breast carcinoma status post chemotherapy completed Year of +204 with weight loss for restaging examination

FDG (F-18-Fluorodeoxyglucose) PET imaging was performed at 1408 hrs approximately 43 minutes following intravenous infusion of the radiopharmaceutical agent using an integrated 16-slice PET/CT scanner. A noncontrast CT scan was performed for attenuation correction of PET data and for anatomic localization. No contrast was administered. Imaging was performed from the skull base to mid thigh levels with subsequent reconstruction of full trunk, orthogonal view slices in transverse, sagittal, and coronal projections which were reviewed along with dynamic multiimage planar and non attenuation corrected sagittal views.

Blood glucose at the time of tracer injection was 86 mg/dl with normal biodistribution of tracer. The quality of this examination is acceptable with regards to count density, processed images, data display and lack of important artifacts (including but not limited to motion and attenuation artifacts except as below).

[page 12 of 18]
+3787

Comparison made with previous PET/CT of [REDACTED] demonstrating stable negative findings for metabolically active disease.

Head/Neck: Stable Beam hardening artifact in the oral cavity. No abnormality of metabolic activity or lymphadenopathy.

Thorax: Mediastinal blood pool maximum SUV is 2.37. No pathologic lymphadenopathy, pulmonary nodularity or focal increase of metabolic activity

Abdomen/Pelvis: Liver maximum SUV is 2.84. There is no focal increase of metabolic activity in solid organs or other soft tissue structures. No lymphadenopathy. Calcified gallstones are present.

Musculoskeletal: Stabilization hardware of the right clavicle is unchanged. No evidence for osseous or muscle metastasis.

IMPRESSION:

Stable negative examination.

No evidence for metabolically active disease, unchanged by comparison.

[REDACTED]

Exceptional Responder # 9671

[REDACTED] (Latest Scan) [REDACTED]

[REDACTED]

[page 13 of 18]
BL imaging = Day 0

[page 14 of 18]
Level 1 case

BL, Day = 0
Axial CT image (left) and sagittal CT image (right). LT breast mass

[page 15 of 18]
Level 1 case

BL, Day = 0

¹⁸F FDG PET CT, sagittal PET image (left)

Increased glucose uptake in breast mass and LNs (arrows)

Enlarged LNs on CT (right) with hypodense centers measured at 17 x 23 mm and 15 x 13 mm.

[page 16 of 18]
Level 1 case

BL, Day 0, (left), BL + 5 months , Day 164 (right)
Enlarged axillary LNs at BL (arrows) are of normal size on follow up

[page 17 of 18]
BL = Day 0

Level 1 case

BL CT: upper left and center, 2 liver mets 39 x 31 mm and 27 x 27 mm

BL = Day 0

PET CT: upper right

BL + 5 months , Day 164 (3 lower images) , smaller liver mets

15 x 12 mm and 7 x 14 mm

Abnormal PET CT:

2 liver lesions
(narrow red arrows)

LT axillary LNs and
breast tumor
(wider green arrows)

RT femur met
(curved yellow arrows)

CT: RT femur met (yellow arrow)

[page 18 of 18]
Surgical Pathology Final Report
Temporary Copy

Case:
Collect:
Ordered by:

ER-ABF0-TTP1-PR

Specimen Source

- A Breast, RIGHT, 2 O'CLOCK
- B Breast, LEFT LOWER OUTER
- C Breast, LEFT UPPER OUTER
- D Breast, LEFT AXILLARY NODE

ICD-0-3
carcinoma, invasive duct, NOS 8500/3
Site: breast, NOS C50.9

ICD-10
C50.912

4/18/16

Clinical Information

- A) Part A is from 2 o'clock, small solid nodule, fibroadenoma versus malignancy.
- B) Left lower outer, invasive malignant mass.
- C) Left upper outer, invasive malignant mass.
- D) Left axillary node, looks involved with metastasis.

The specimen was placed in formalin at
formalin fixation guidelines.

The specimen will meet

Gross Description

Part A. Submitted in a container of formalin labelled [REDACTED] #1, right 2 o'clock" are four tan needle core biopsies ranging in size from 1.1 to 0.7 cm in length. They are submitted entirely in A1.

Gross Summary:

Specimen Type: needle biopsies
Laterality: right
Tumor Site: 2 o'clock
Time in Formalin Between 6 and 48 Hours (Yes/No): yes

Part B. Submitted in a container of formalin labelled [REDACTED] #2, left lower outer" are four tan needle core biopsies ranging in size from 1.5 to 1 cm in length. They are submitted entirely in B1.

Gross Summary:

Specimen Type: needle biopsies
Laterality: left
Tumor Site: lower outer
Time in Formalin Between 6 and 48 Hours (Yes/No): yes

Part C. Submitted in a container of formalin labelled [REDACTED] #3, upper outer" are four tan needle core biopsies ranging in size from 2.7 to 1.7 cm in length. They are submitted entirely in C1.

Gross Summary:

Specimen Type: needle biopsies
Laterality: left

Source: NCI Genomic Data Commons file 0c2ccd05-7695-442e-861c-17d0c99f9bad (ER0075 ER-ABF0 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).